Surgical pathology report (de-identified scan), TCGA case TCGA-HT-8011, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western - St Joes, specimen TCGA-HT-8011-01A (Primary Tumor).

Microscopic

The neoplastic cells demonstrate variably strong GFAP positivity. The granular cytoplasm is also reactive, although often weaker than in other areas. The granules are positive for both PAS and PAS with diastase consistent with lysosommal origin, as was expected in agranular astrocytoma. Numerous MIB-1 reactive cells are present and a labeling index of 33% is calculated

Diagnosis

**Anaplastic astrocytoma grade III,
Granular cell subtype**

Source: NCI Genomic Data Commons file d7a1170f-8a08-4436-a35a-9c4469e50424 (TCGA-HT-8011.67C30FD5-6FF5-49B7-B0E6-4006EF4510FC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).